Somatic mutation profile of tumor specimen TCGA-S9-A7IZ-01A (aliquot TCGA-S9-A7IZ-01A-11D-A34A-08) from TCGA case TCGA-S9-A7IZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.9 years (17,874 days).
Specimen TCGA-S9-A7IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2262b665-cb02-4c18-a89e-c71e15d05906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7IZ-10A (Blood Derived Normal), aliquot TCGA-S9-A7IZ-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3ab41f0-38a8-4dd9-a5b6-de6c3435277d

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 11, Frame Shift Del 4, Intron 1, Splice Site 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 32/85 reads (38%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- BCAN | c.2111C>A p.S704Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100228272; called by muse, mutect2, varscan2
- C8orf33 | c.339A>T p.E113D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100510565; called by muse, mutect2, varscan2
- CAMKK2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV100243070; called by muse, mutect2, varscan2
- CAMKMT | c.377-2A>C p.X126_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as COSV101035069; called by muse, varscan2
- ELOVL4 | c.49_50insGGA p.S16_T17insR | In Frame Ins (INS) | VAF 4/42 reads (10%) | catalogued as CI1415064; called by mutect2, pindel
- EVI5 | c.2368A>G p.S790G | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100945414; called by muse, mutect2, varscan2
- FGD1 | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs748539098, COSV64307970; called by muse, mutect2, varscan2
- IARS2 | c.1336A>T p.M446L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.389); catalogued as COSV100228440; called by muse, varscan2
- IGHV1OR21-1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs370370045; called by muse, mutect2, varscan2
- NBEA | c.7883G>T p.R2628I | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100082049; called by muse, mutect2, varscan2
- OR2D2 | c.479C>G p.T160S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV100203883; called by muse, mutect2, varscan2
- PAK5 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs767541766, COSV62036261; called by muse, mutect2, varscan2
- PHLDB1 | c.3416G>A p.S1139N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs1429972711, COSV100616648; called by muse, mutect2, varscan2
- PSME4 | c.3161C>T p.P1054L | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.092); catalogued as COSV101122569; called by muse, mutect2, varscan2
- RGS6 | c.999G>A p.W333* | Nonsense Mutation (SNP) | VAF 57/151 reads (38%) | catalogued as COSV100666579; called by muse, mutect2, varscan2
- THBS3 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100857658; called by muse, mutect2
- XPC | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as COSV99542450; called by muse, varscan2
- ZAN | c.4618G>A p.A1540T | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs974439732, COSV61809515; called by muse, mutect2, varscan2
- ZCCHC12 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100038599; called by muse, mutect2, varscan2
- ARL4A | c.405_408del p.Q136Ifs*2 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by pindel, varscan2
- ATRX | c.1819del p.E607Kfs*14 | Frame Shift Del (DEL) | VAF 152/508 reads (30%) | called by mutect2, pindel, varscan2
- CDKN1B | c.176del p.K59Sfs*12 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADGRL2 | c.4116T>C p.Y1372= (on ENST00000370717 / NM_001366005.1; = p.Y1316= on NM_012302.4) | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99590114; called by muse, mutect2, varscan2
- AMOTL1 | c.501G>A p.V167= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100133858; called by muse, mutect2, varscan2
- CACNA1G | c.639C>T p.N213= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs377421647; called by muse, mutect2, varscan2
- DCAF12L2 | c.1002G>A p.P334= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as rs745642585, COSV63580297; called by muse, mutect2, varscan2
- DIP2A | c.510C>T p.V170= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV100596097; called by muse, mutect2
- MYBL1 | c.1482A>G p.T494= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs1222179868, COSV101576570; called by muse, mutect2, varscan2
- TLL1 | c.804C>A p.I268= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99287992; called by muse, mutect2, varscan2
- TRAV3 | c.336G>A p.V112= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1478952528; called by muse, mutect2
- WSCD2 | c.267C>T p.Y89= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs375207995; called by muse, mutect2, varscan2
- ZBTB46 | c.99C>A p.V33= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99829413; called by muse, mutect2, varscan2
- ZNF234 | c.405G>A p.R135= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV101468382; called by muse, mutect2, varscan2
- FLAD1 | c.1555-79T>C | Intron (SNP) | VAF 23/58 reads (40%) | catalogued as rs1358803211, COSV99422728; called by muse, mutect2, varscan2
